Gene-level copy-number profile of tumor specimen C3L-09778-03 from CPTAC case C3L-09778, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 67.6 years (24,677 days).
Specimen C3L-09778-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 792223ee-e949-4deb-8529-8659e36e2044.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-09778-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,740 have no estimate.
https://portal.gdc.cancer.gov/files/b5b078c2-c4ae-4f51-9a37-92fcf9c689dc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 1: 670; copy number 2: 27,200; copy number 3: 12,602; copy number 4: 16,198; copy number 5: 1,308; copy number 6: 742; copy number 7: 56; copy number 8: 29; copy number 9: 9; copy number 38: 2; copy number 40: 3; copy number 43: 9; copy number 45: 1; copy number 48: 1; copy number 53: 4; copy number 62: 1; copy number 75: 1; copy number 76: 1; copy number 115: 3; copy number 118: 1; copy number 128: 4; copy number 156: 3; copy number 157: 2; copy number 352: 2; copy number 529: 1.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:12,064,389–12,177,550, 10 genes (within-gene range 0–3): DEFB130B, RNA5SP253, DEFB108D, ZNF705D, FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P.
- chr10:87,607,985–87,971,930, 11 genes: AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3.
- chr16:78,825,281–79,017,429, 7 genes (within-gene range 0–2): RPS3P7, AC136603.1, AC027279.4, AC027279.1, AC027279.3, AC027279.2, AC009145.4.
- chr21:44,107,373–44,210,114, 2 genes (within-gene range 0–2): PWP2, GATD3A.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,183 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,769,083, 17 genes, copy number 5: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P.
- chr4:6,687,448–6,717,664, 5 genes, copy number 5: LINC02481, AC093323.2, S100P, MRFAP1L1, BLOC1S4.
- chr5:58,198–45,895,970, 679 genes, copy number 6–8 (broad region; genes not listed).
- chr6:30,414,715–30,597,179, 10 genes, copy number 6: MICC, TMPOP1, SUCLA2P1, RANP1, HLA-E, LINC02569, GNL1, PRR3, ABCF1, MIR877.
- chr7:67,278,714–67,302,419, 3 genes, copy number 6: SPDYE21, PMS2P4, Y_RNA.
- chr7:135,774,521–136,437,785, 7 genes, copy number 6 (within-gene range 4–6): AC015987.1, MTPN, RNU6-223P, AC024084.1, AC078845.1, Y_RNA, AC009784.1.
- chr7:151,238,764–151,277,896, 1 gene, copy number 6 (within-gene range 4–6): SMARCD3.
- chr7:151,341,699–159,233,377, 124 genes, copy number 5–6 (broad region; genes not listed).
- chr8:122,781,655–122,974,510, 1 gene, copy number 62 (within-gene range 2–62): ZHX2.
- chr8:122,977,026–123,042,302, 3 genes, copy number 156 (within-gene range 2–156): AC104316.2, AC104316.1, DERL1.
- chr8:123,416,726–123,541,206, 3 genes, copy number 40: NTAQ1, U4, FBXO32.
- chr8:123,614,219–123,737,402, 3 genes, copy number 38–75: AC135166.1, KLHL38, ANXA13.
- chr8:124,192,671–124,301,804, 4 genes, copy number 53: AC090921.1, RNU6-756P, AC090192.2, AC090192.1.
- chr8:124,811,042–124,857,516, 1 gene, copy number 48 (within-gene range 2–128): AC100858.2.
- chr8:124,823,702–124,962,531, 4 genes, copy number 128 (within-gene range 48–128): LINC00964, MRS2P1, AC100858.1, AC100858.3.
- chr8:125,430,358–125,541,373, 2 genes, copy number 45–118 (within-gene range 2–118): TRIB1, AC091114.1.
- chr8:127,289,817–127,482,139, 1 gene, copy number 115 (within-gene range 2–115): CASC8.
- chr8:127,322,183–128,220,803, 17 genes, copy number 43–529: POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226.
- chr9:65,282,101–65,285,209, 1 gene, copy number 9: FOXD4L5.
- chr9:118,687,752–119,524,125, 5 genes, copy number 6: AL355592.1, LINC02578, TUBB4BP6, BRINP1, AC006288.1.
- chr9:138,137,095–138,253,217, 5 genes, copy number 5: IL9RP1, TUBBP5, AL591424.2, AL954642.1, FAM157B.
- chr12:1,380,060–2,954,338, 46 genes, copy number 5 (within-gene range 3–5): AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14, MIR3649, ADIPOR2, AC005183.1, AC005343.4, RPS4XP14, CACNA2D4, AC005343.7, LRTM2, AC005342.2, LINC00940, DCP1B, CACNA1C, AC005342.1, CACNA1C-IT1, CACNA1C-IT2, AC005344.1, CACNA1C-AS4, CACNA1C-IT3, AC005293.1, AC005414.1, CACNA1C-AS3, AC007618.1, CACNA1C-AS2, CACNA1C-AS1, ITFG2-AS1, LINC02371, IQSEC3P1, AC092471.1, RPL23AP14, CBX3P4, FKBP4, ITFG2-AS1, AC005841.1, ITFG2, NRIP2, TEX52, FOXM1, RHNO1, TULP3, AC005911.1, RNU6-1315P.
- chr13:18,467,172–18,697,507, 9 genes, copy number 5: ZNF962P, BNIP3P7, LINC00349, LONRF2P2, LINC00388, FEM1AP4, LINC00387, TERF1P5, FAM207BP.
- chr13:98,445,185–99,086,625, 13 genes, copy number 6 (within-gene range 4–6): STK24, AL356423.1, STK24-AS1, NUS1P4, CYCSP35, CALM2P4, RN7SL60P, SLC15A1, DOCK9, DOCK9-AS1, AL161420.1, RPL7L1P12, RNU6-83P.
- chr14:18,333,726–21,456,126, 184 genes, copy number 5–6 (broad region; genes not listed).
- chr20:13,714,322–13,996,443, 4 genes, copy number 6 (within-gene range 4–6): ESF1, NDUFAF5, SEL1L2, RNU6-278P.
- chr20:18,782,424–35,147,336, 329 genes, copy number 5 (broad region; genes not listed).
- chr20:35,302,566–64,327,972, 702 genes, copy number 5–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 670. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
